Gene-level copy-number profile of tumor specimen TCGA-25-2400-01A from TCGA case TCGA-25-2400, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 76.1 years (27,789 days).
Specimen TCGA-25-2400-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.0f0a599b-d0df-44be-811c-d79bbfa918cf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-25-2400-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 821 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1fc3f0b5-ca28-4f19-812a-63fb29f60ed7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 226; copy number 2: 11,067; copy number 3: 16,067; copy number 4: 15,319; copy number 5: 10,029; copy number 6: 3,264; copy number 7: 2,081; copy number 8: 741; copy number 9: 200; copy number 10: 116; copy number 12: 54; copy number 13: 53; copy number 14: 160; copy number 15: 81; copy number 16: 91; copy number 17: 55; copy number 21: 15; copy number 22: 45; copy number 25: 18; copy number 29: 27; copy number 31: 93.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-25-2400-01A-01D-0704-01): tumor purity 0.83, ploidy 3.72, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,763 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,831,007–10,452,153, 59 genes, copy number 7–9: RPL23AP19, ENO1, MIR6728, ENO1-AS1, RNU6-304P, HMGN2P17, AL139415.1, AL139415.2, CA6, RN7SL451P, SLC2A7, SLC2A5, AL158048.1, GPR157, MIR34AHG, MIR34A, LNCTAM34A, H6PD, SPSB1, BX323043.1, LINC02606, RNA5SP40, AL928921.1, SLC25A33, AL954705.1, TMEM201, PIK3CD, PIK3CD-AS1, AL691449.1, PIK3CD-AS2, CLSTN1, MZT1P1, AL357140.3, CTNNBIP1, AL357140.1, AL357140.4, LZIC, AL357140.2, NMNAT1, RN7SKP269, TMEM274P, MIR5697, AL603962.1, RBP7, UBE4B, AL590639.1, PGAM1P11, RNU6-828P, KIF1B, AL358013.1, RNU6-37P, RN7SL731P, AL139424.3, AL139424.2, PGD, AL139424.1, CENPS-CORT, CENPS, CORT.
- chr1:13,389,632–13,825,079, 10 genes, copy number 9: PRAMEF17, PRAMEF20, LRRC38, AL354712.1, BRWD1P1, PDPN, RNA5SP41, AL359771.1, AL359771.2, PRDM2.
- chr1:35,122,022–37,765,133, 72 genes, copy number 22–29 (broad region; genes not listed).
- chr1:38,474,825–43,156,396, 145 genes, copy number 14–31 (broad region; genes not listed).
- chr1:43,171,652–43,171,712, 1 gene, copy number 16: MIR6733.
- chr1:43,196,417–43,196,536, 1 gene, copy number 16: RNA5SP46.
- chr2:29,060,976–35,725,142, 89 genes, copy number 13–16 (broad region; genes not listed).
- chr2:41,716,133–56,750,563, 242 genes, copy number 8–17 (broad region; genes not listed).
- chr2:57,907,629–63,827,843, 101 genes, copy number 8–14 (within-gene range 5–14) (broad region; genes not listed).
- chr2:73,947,322–77,593,319, 93 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr3:172,889,357–174,378,005, 8 genes, copy number 7 (within-gene range 5–7): SPATA16, AC068759.1, NLGN1, AC092967.1, NLGN1-AS1, RN7SKP234, ANAPC15P2, AC069218.1.
- chr4:72,031,804–73,456,174, 14 genes, copy number 7: NPFFR2, ADAMTS3, AC095056.1, HNRNPA1P67, RNU4ATAC9P, RNU6ATAC5P, COX18, ANKRD17, HMGA1P2, AC053527.2, AC053527.1, AC108157.1, ALB, AFP.
- chr5:36,485,343–40,269,719, 62 genes, copy number 8 (broad region; genes not listed).
- chr5:41,142,116–45,895,970, 74 genes, copy number 8 (broad region; genes not listed).
- chr6:49,273,600–58,438,364, 152 genes, copy number 7 (broad region; genes not listed).
- chr7:30,852,273–35,379,675, 65 genes, copy number 7–9 (broad region; genes not listed).
- chr7:46,476,457–47,629,893, 13 genes, copy number 7: AC004869.2, AC004869.1, HMGN1P19, AC011294.1, EPS15P1, AC004870.4, AC004870.2, AC004870.3, MRPL42P4, AC004870.1, AC087175.1, TNS3, LINC01447.
- chr7:56,493,124–57,485,895, 63 genes, copy number 7 (broad region; genes not listed).
- chr7:76,902,480–87,909,553, 114 genes, copy number 7 (broad region; genes not listed).
- chr9:60,914,407–69,009,176, 182 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr10:3,009,976–5,304,865, 52 genes, copy number 8–16: AL731533.1, AL731533.3, AL731533.2, PFKP, AL451164.2, PITRM1, PITRM1-AS1, AL451164.3, AL451164.1, LINC02668, AL139280.1, AL139280.3, AL139280.2, AL356433.1, LINC02669, AL357833.1, AL450322.2, AL450322.1, KLF6, AL513303.1, LINC02639, LINC02660, MIR6078, AC025822.1, AC025822.2, LINC00702, LINC00703, AC022535.1, AC022535.3, AC022535.2, RNU6-163P, MANCR, LINC00705, AC018978.1, AKR1E2, AKR1C6P, U8, AKR1C1, AKR1C2, AL391427.1, U8, AKR1C3, U8, AKR1C5P, AKR1C8P, AKR1C4, ARL4AP3, AL355303.2, AL355303.1, LINC02561, AKR1C7P, RPL26P28.
- chr12:23,529,504–27,972,733, 90 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr12:28,163,298–28,236,828, 4 genes, copy number 7: AC022364.1, AC022364.2, AC022079.2, AC022079.1.
- chr12:57,415,296–70,434,292, 275 genes, copy number 7–21 (within-gene range 6–21) (broad region; genes not listed).
- chr14:18,333,726–22,053,056, 235 genes, copy number 7 (broad region; genes not listed).
- chr14:27,258,717–27,845,286, 3 genes, copy number 8 (within-gene range 8–15): AL390334.1, LINC00645, MIR3171.
- chr14:86,905,778–106,875,071, 756 genes, copy number 7 (broad region; genes not listed).
- chr16:4,130,555–7,726,951, 79 genes, copy number 7–15 (within-gene range 3–15) (broad region; genes not listed).
- chr16:14,435,700–16,223,522, 62 genes, copy number 8–25 (within-gene range 3–25) (broad region; genes not listed).
- chr19:9,560,329–10,517,931, 58 genes, copy number 8 (within-gene range 3–8): ZNF121, ZNF561, ZNF561-AS1, ZNF562, RPS4XP22, ZNF812P, AC008759.3, AC008759.1, AC008759.2, ZNF846, AC008752.3, UBE2L4, AC008752.1, FBXL12, SNORA70, RPL10P15, UBL5, AC008752.2, PIN1, OLFM2, COL5A3, AC008742.1, RDH8, C3P1, MIR5589, SHFL, AC020931.1, ANGPTL6, PPAN-P2RY11, PPAN, SNORD105, SNORD105B, P2RY11, EIF3G, DNMT1, S1PR2, MIR4322, MRPL4, AC011511.2, AC011511.3, ICAM1, AC011511.5, ICAM4, ICAM5, ZGLP1, AC011511.1, FDX2, AC011511.4, RAVER1, AC114271.1, ICAM3, TYK2, CDC37, MIR1181, PDE4A, KEAP1, AC011461.1, S1PR5.
- chr19:11,925,068–19,857,527, 457 genes, copy number 7–8 (broad region; genes not listed).
- chr19:19,870,723–19,871,299, 1 gene, copy number 8: BNIP3P10.
- chr20:7,146,467–8,043,512, 11 genes, copy number 7 (within-gene range 5–7): LINC01428, AL080248.1, LINC01751, LINC01706, MIR8062, RN7SL547P, AL031679.1, AL021879.1, HAO1, TMX4, AL021396.1.
- chr20:8,097,824–8,256,918, 2 genes, copy number 7: PHKBP1, PLCB1-IT1.
- chr20:25,099,105–32,050,705, 118 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 226. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
